FM case AD3095 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/6753b94f-07c9-4e6a-9c14-86322d23b783

Female, 49.0 years: Carcinoma, NOS (ICD-O-3 8010/3); specimen biopsied or resected from the heart. Tumor nuclei on the sequenced sample's slide: 70% (pathologist estimate recorded by GDC). Sample type: Tumor.
